Somatic mutation profile of tumor specimen 0D88RN from CCDI case PBBHCR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloepithelioma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 12.3 years (4,503 days).
Specimen 0D88RN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72560a36-fc77-46d8-a5f9-abeda704bccc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D88RQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46474e7c-9fa8-4e7c-9897-19fd4ad9be9b

The open-access MAF lists 73 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 13, Intron 6, 5'UTR 3, 3'UTR 3, Nonsense Mutation 2, Splice Region 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR1 | c.10347+1G>A p.X3449_splice | Splice Site (SNP) | VAF 24/176 reads (14%) | catalogued as rs111436401, CS157285; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.4120G>A p.G1374R | Missense Mutation (SNP) | VAF 123/923 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99687121; called by muse, mutect2, varscan2
- AKR7L | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 42/353 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs373020968; called by muse, varscan2
- APBA2 | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 93/630 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as rs371370074; called by muse, mutect2, varscan2
- CHD5 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 75/598 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs1363035377, COSV52427754, COSV99315729; called by muse, mutect2, varscan2
- DNHD1 | c.13285C>T p.R4429* | Nonsense Mutation (SNP) | VAF 50/483 reads (10%) | catalogued as rs201400447, COSV54432585; called by muse, mutect2, varscan2
- EMC8 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 25/558 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263786800, COSV99495689; called by muse, mutect2
- FAM167B | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751979021; called by muse, mutect2, varscan2
- GLCCI1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 104/707 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99780457; called by muse, mutect2, varscan2
- GPR78 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.204); catalogued as rs1224850260, COSV66763287; called by muse, mutect2
- HDAC6 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 15/351 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs188264171; called by muse, mutect2
- HSF1 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 21/678 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs1554843873, COSV68821686; called by muse, mutect2
- JAK2 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 123/2510 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.738); catalogued as rs141554173, COSV101077092; called by muse, mutect2
- KRT2 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 32/402 reads (8%) | catalogued as rs571471637, COSV59010753; ClinVar: likely benign; called by muse, mutect2
- LMF1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 94/233 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.351); catalogued as rs1245919258; called by muse, mutect2, varscan2
- PCDHB2 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 60/796 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.052); catalogued as rs1554271414, COSV50565104; called by muse, mutect2
- PCDHGA10 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.791); catalogued as rs1337575676, COSV99543530; called by muse, mutect2, varscan2
- PLCB2 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs768839429, COSV53031582; called by mutect2, varscan2
- RIMBP2 | c.2852C>T p.S951L | Missense Mutation (SNP) | VAF 159/777 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs750902645, COSV55474305; called by muse, mutect2, varscan2
- SLIT2 | c.2746C>G p.L916V | Missense Mutation (SNP) | VAF 64/808 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs1227297157; called by muse, mutect2
- SPEG | c.5387C>T p.P1796L | Missense Mutation (SNP) | VAF 54/971 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1449579385; called by muse, mutect2
- ST8SIA5 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 467/891 reads (52%) | PolyPhen benign (0.015); catalogued as rs772209308, COSV59330330; called by muse, mutect2, varscan2
- STX1B | c.786+6C>T | Splice Region (SNP) | VAF 80/194 reads (41%) | catalogued as rs750134526, COSV99288389; ClinVar: likely benign; called by muse, varscan2
- STYK1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 139/578 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs200398907; called by muse, mutect2, varscan2
- TMEM132E | c.2320G>A p.V774M (on ENST00000321639; = p.V864M on NM_001304438.2) | Missense Mutation (SNP) | VAF 38/546 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs772756078; called by muse, mutect2
- ACTL7A | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 93/924 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); called by muse, mutect2
- APOOL | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 115/582 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BTG3 | c.91G>C p.A31P | Missense Mutation (SNP) | VAF 216/1385 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CSN1S1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 30/1038 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.114); called by muse, mutect2
- CUBN | c.1174T>C p.C392R | Missense Mutation (SNP) | VAF 215/896 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX58 | c.2542C>A p.P848T | Missense Mutation (SNP) | VAF 168/1552 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); called by mutect2, varscan2
- DNAH10 | c.1087G>A p.V363I (on ENST00000409039; = p.V302I on NM_207437.3) | Missense Mutation (SNP) | VAF 72/856 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2
- DUSP6 | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 33/409 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- FRY | c.8824G>T p.D2942Y | Missense Mutation (SNP) | VAF 74/1061 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- GUCY2F | c.511T>A p.S171T | Missense Mutation (SNP) | VAF 140/663 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IL36A | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 66/952 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.063); called by muse, mutect2
- KIF2B | c.752A>T p.Q251L | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OS9 | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 55/846 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.282); called by muse, mutect2
- P2RY4 | c.693G>T p.L231F | Missense Mutation (SNP) | VAF 137/487 reads (28%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.722); called by mutect2, varscan2
- PXDN | c.2647C>A p.P883T | Missense Mutation (SNP) | VAF 39/508 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- RPS5 | c.342C>A p.N114K | Missense Mutation (SNP) | VAF 100/1046 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.072); called by muse, mutect2
- SLC16A2 | c.1558C>G p.P520A | Missense Mutation (SNP) | VAF 33/599 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.021); called by muse, mutect2
- SNX18 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 160/634 reads (25%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- SPATA31D3 | c.2556C>G p.H852Q | Missense Mutation (SNP) | VAF 36/1414 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2
- UBR4 | c.12703G>A p.G4235S | Missense Mutation (SNP) | VAF 73/443 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- ZCCHC7 | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 104/1502 reads (7%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ZNF488 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APOA5 | c.729C>T p.H243= | Silent (SNP) | VAF 110/564 reads (20%) | catalogued as rs760626837, COSV57062987, COSV57065674; called by muse, mutect2, varscan2
- AWAT1 | c.906T>C p.Y302= | Silent (SNP) | VAF 93/640 reads (15%) | called by muse, mutect2, varscan2
- COL12A1 | c.8898C>T p.G2966= | Silent (SNP) | VAF 76/723 reads (11%) | called by muse, mutect2, varscan2
- COL5A2 | c.3849C>A p.R1283= | Silent (SNP) | VAF 61/1234 reads (5%) | called by muse, mutect2
- CT47B1 | c.795C>T p.P265= | Silent (SNP) | VAF 94/1866 reads (5%) | catalogued as rs1437020414, COSV64890353, COSV64891300; called by muse, mutect2
- DMRT2 | c.156C>T p.D52= | Silent (SNP) | VAF 58/794 reads (7%) | called by muse, mutect2
- DOCK11 | c.1500T>A p.S500= | Silent (SNP) | VAF 46/732 reads (6%) | called by muse, mutect2
- GRIN3A | c.39C>A p.V13= | Silent (SNP) | VAF 38/1370 reads (3%) | called by muse, mutect2
- KLHL17 | c.408C>T p.H136= | Silent (SNP) | VAF 34/204 reads (17%) | called by muse, mutect2, varscan2
- OAS2 | c.102C>A p.I34= | Silent (SNP) | VAF 78/383 reads (20%) | catalogued as COSV60804831; called by muse, mutect2, varscan2
- OVGP1 | c.1851A>G p.E617= | Silent (SNP) | VAF 64/464 reads (14%) | called by muse, mutect2
- SLC9A7 | c.1288C>T p.L430= | Silent (SNP) | VAF 72/633 reads (11%) | called by muse, mutect2, varscan2
- SOST | c.297G>A p.P99= | Silent (SNP) | VAF 78/431 reads (18%) | catalogued as rs1038749159; called by muse, mutect2, varscan2
- ADTRP | c.-43G>A | 5'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2, varscan2
- ALAS2 | c.-15-1824C>T | Intron (SNP) | VAF 28/246 reads (11%) | catalogued as COSV100238525; called by mutect2, varscan2
- C17orf49 | c.515-52_515-43del | Intron (DEL) | VAF 30/156 reads (19%) | called by mutect2, varscan2
- CCDC114 | c.*14C>T | 3'UTR (SNP) | VAF 26/209 reads (12%) | catalogued as rs765196045, COSV59557799; called by muse, mutect2, varscan2
- DPP9 | chr19:4676561 G>A | 3'Flank (SNP) | VAF 61/192 reads (32%) | called by muse, varscan2
- H4C2 | c.*75T>C | 3'UTR (SNP) | VAF 14/164 reads (9%) | catalogued as rs891160941; called by muse, mutect2
- LIMS2 | c.510-64C>T | Intron (SNP) | VAF 34/114 reads (30%) | catalogued as rs573367087; called by muse, mutect2, varscan2
- MTSS1 | c.727-88G>A | Intron (SNP) | VAF 4/20 reads (20%) | catalogued as rs1002273632, COSV100275652; called by muse, mutect2
- NFKB1 | c.*35G>A | 3'UTR (SNP) | VAF 54/560 reads (10%) | catalogued as rs747763124; called by muse, mutect2, varscan2
- NUDT1 | c.-56T>C | 5'UTR (SNP) | VAF 15/185 reads (8%) | called by muse, mutect2
- POSTN | c.2431+71G>A | Intron (SNP) | VAF 38/166 reads (23%) | called by mutect2, varscan2
- RNF44 | c.927-59G>A | Intron (SNP) | VAF 25/108 reads (23%) | catalogued as rs892835715; called by muse, mutect2, varscan2
- TNFSF4 | c.-51G>T | 5'UTR (SNP) | VAF 48/197 reads (24%) | catalogued as rs779229208, COSV99919567; called by muse, mutect2, varscan2
